Somatic mutation profile of tumor specimen TCGA-RY-A83Z-01A (aliquot TCGA-RY-A83Z-01A-11D-A36O-08) from TCGA case TCGA-RY-A83Z, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 54.5 years (19,903 days).
Specimen TCGA-RY-A83Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a13a1b7f-4595-4176-8d16-744bea1c4a26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RY-A83Z-10A (Blood Derived Normal), aliquot TCGA-RY-A83Z-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a472d8b-3017-4197-b6f6-b3fa04292fe5

The open-access MAF lists 50 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Frame Shift Del 2, Nonsense Mutation 2, 5'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 38/107 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 60/69 reads (87%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- WDR72 | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs557128345, CM109077, COSV64751129; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.9C>A p.S3R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs1383749447, COSV99635114; called by muse, varscan2
- ADAM28 | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs1259902388, COSV99737783; called by muse, mutect2
- ADGRG4 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99794370; called by muse, mutect2, varscan2
- ATP12A | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV99517020; called by muse, mutect2, varscan2
- ATP6AP1 | c.1232A>T p.Q411L | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV100870651; called by muse, mutect2, varscan2
- BCL9 | c.1209A>C p.E403D | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99324492; called by muse, mutect2, varscan2
- CATSPERB | c.2941C>T p.H981Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99830819; called by muse, mutect2, varscan2
- CD177 | c.406T>A p.C136S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100945804; called by mutect2, varscan2
- CFAP47 | c.497C>G p.T166S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99934405; called by muse, mutect2, varscan2
- CR1 | c.2728T>C p.F910L | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV100887394; called by muse, mutect2, varscan2
- CRYM | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.195); catalogued as COSV99561576; called by muse, mutect2, varscan2
- DNAJA1 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs144405670; called by muse, mutect2, varscan2
- FANCD2 | c.3860G>A p.S1287N | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99810345, COSV99811141; called by muse, mutect2, varscan2
- KMT2C | c.12745A>G p.T4249A | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs910828769, COSV100066954; called by muse, mutect2, varscan2
- LGALS1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs1389013302, COSV53222309; called by muse, mutect2, varscan2
- MAP3K15 | c.3863G>T p.G1288V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448110764, COSV100134037; called by muse, mutect2, varscan2
- NADSYN1 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.091); catalogued as COSV100034429; called by muse, mutect2
- OR1G1 | c.291T>G p.C97W | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100187501; called by muse, mutect2, varscan2
- OSBPL3 | c.2563T>C p.F855L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100513700; called by muse, mutect2, varscan2
- PAQR8 | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100658379; called by muse, mutect2, varscan2
- PHEX | c.1977A>T p.K659N | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.239); catalogued as COSV101039399; called by muse, mutect2, varscan2
- PLEKHS1 | c.452T>A p.F151Y (on ENST00000369310 / NM_182601.1; = p.F157Y on NM_024889.5) | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (1); PolyPhen possibly damaging (0.49); catalogued as COSV100612944; called by muse, mutect2, varscan2
- RBX1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99345334; called by muse, mutect2, varscan2
- SETD9 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV99605534, COSV99605554; called by muse, mutect2, varscan2
- SH3TC1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as rs371734585, COSV55283227; called by muse, mutect2, varscan2
- SLC16A2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.349); catalogued as rs766492237, COSV52084080; called by muse, mutect2, varscan2
- SLC17A2 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.498); catalogued as COSV99613897; called by muse, mutect2, varscan2
- TIMELESS | c.3568G>A p.G1190R | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV99973618; called by muse, mutect2, varscan2
- USP24 | c.6098A>C p.N2033T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99598867; called by muse, mutect2, varscan2
- XKR9 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101281819; called by muse, mutect2, varscan2
- ZXDA | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.793); catalogued as COSV62388324; called by muse, mutect2, varscan2
- ATRX | c.4888dup p.T1630Nfs*8 | Frame Shift Ins (INS) | VAF 34/96 reads (35%) | called by mutect2, pindel, varscan2
- DGKA | c.2077del p.L693Ffs*42 | Frame Shift Del (DEL) | VAF 125/324 reads (39%) | called by mutect2, pindel, varscan2
- HDAC2 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP9 | c.2482T>A p.C828S | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- PLG | c.1448_1449del p.F483Wfs*29 | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- CFP | c.1068C>T p.D356= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs775387328, COSV99901299; called by muse, mutect2, varscan2
- FSIP2 | c.16551A>G p.K5517= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV100554030; called by muse, mutect2, varscan2
- GPR139 | c.813C>T p.N271= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs1324519051, COSV100429627; called by muse, mutect2
- LILRB5 | c.987G>A p.Q329= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as COSV100300067; called by muse, mutect2, varscan2
- MAP3K4 | c.426G>A p.Q142= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100815038; called by muse, mutect2, varscan2
- MYO3A | c.3975T>A p.R1325= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV99778364; called by muse, mutect2
- OR8H1 | c.162G>A p.Q54= | Silent (SNP) | VAF 118/243 reads (49%) | catalogued as COSV100476826; called by muse, mutect2, varscan2
- RELN | c.3633G>A p.Q1211= | Silent (SNP) | VAF 10/304 reads (3%) | catalogued as COSV100632507; called by muse, mutect2
- ZXDA | c.1095C>T p.C365= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs1329314447, COSV62387414; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501435 C>A | 5'Flank (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- HERC2P3 | n.1792A>G | RNA (SNP) | VAF 48/125 reads (38%) | catalogued as rs1287096574; called by muse, mutect2, varscan2
